Somatic mutation profile of tumor specimen TCGA-VD-AA8O-01A (aliquot TCGA-VD-AA8O-01A-11D-A39W-08) from TCGA case TCGA-VD-AA8O, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.3 years (28,250 days).
Specimen TCGA-VD-AA8O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 717dcbba-f34a-4705-af5c-5d61be3421a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8O-10A (Blood Derived Normal), aliquot TCGA-VD-AA8O-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d9c1628-e0fd-40e9-8b9f-a0d8e0140a88

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYSLTR2 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 45/187 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56166671; called by muse, mutect2, varscan2
- KCNH5 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777164, CM1310653, COSV59758318, COSV59758899; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABR | c.1485C>T p.D495= (on ENST00000302538 / NM_021962.5; = p.D458= on NM_001092.5) | Splice Region (SNP) | VAF 96/238 reads (40%) | catalogued as rs771481181; called by muse, mutect2
- ASIC1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs764353781; called by muse, mutect2, varscan2
- ILVBL | c.987C>A p.H329Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV99655165; called by muse, mutect2
- AC004922.1 | c.1325A>G p.K442R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ASPM | c.1846A>C p.K616Q | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FAM217A | c.651C>G p.S217R | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- GAB1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTR3E | c.243G>T p.Q81H (on ENST00000415389 / NM_001256613.1; = p.Q96H on NM_182589.2) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PLXNA4 | c.1925C>T p.T642I | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF474 | c.792_842del p.K265_Q281del | In Frame Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- ASPM | c.1845G>A p.K615= | Silent (SNP) | VAF 82/162 reads (51%) | catalogued as COSV54126894; called by muse, mutect2, varscan2
- STRIP2 | c.2307C>T p.A769= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
